Somatic mutation profile of tumor specimen ALCH-B1ZF-TTP1-A (aliquot ALCH-B1ZF-TTP1-A-3-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.0 years (19,727 days).
Specimen ALCH-B1ZF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4023be61-c55f-4d57-bcea-cfb5cc478222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZF-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZF-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f9c4b40-c54a-4ca3-acc8-5b636388c203

The open-access MAF lists 118 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 25, Intron 8, Nonsense Mutation 6, Frame Shift Del 2, 5'UTR 2, 3'UTR 2, Splice Site 2, Nonstop Mutation 1, In Frame Del 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 291/834 reads (35%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 156/527 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57052365; called by muse, mutect2
- ADGRA2 | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as rs1383182850; called by muse, mutect2
- AMTN | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 32/177 reads (18%) | catalogued as COSV59489820; called by muse, mutect2, varscan2
- CCL28 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370644785; called by muse, mutect2, varscan2
- COL6A3 | c.5678C>T p.T1893M | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs143389941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.2191C>A p.P731T | Missense Mutation (SNP) | VAF 58/968 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV57880979; called by muse, mutect2
- CUBN | c.7570G>A p.E2524K | Missense Mutation (SNP) | VAF 20/504 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.091); catalogued as COSV100911717; called by muse, mutect2
- ELFN1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774091154, COSV70035797; called by muse, mutect2
- ENTPD3 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs867124613; called by muse, mutect2
- FAM155A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65566542; called by muse, mutect2, varscan2
- FAM83H | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs781947548; called by muse, mutect2, varscan2
- FSCB | c.2224C>A p.P742T | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs752113455; called by muse, varscan2
- GRIN2B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 25/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74207138; called by muse, mutect2
- HES1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs974048986; called by muse, mutect2, varscan2
- KIAA1522 | c.193C>G p.Q65E (on ENST00000373480 / NM_001198972.2; = p.Q124E on NM_020888.3) | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.3); catalogued as COSV53865456; called by muse, mutect2, varscan2
- KMT2D | c.15499A>G p.S5167G | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752976776; ClinVar: uncertain significance; called by muse, mutect2
- KRT85 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 123/898 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs749656522, COSV99225473; called by muse, mutect2, varscan2
- MARCHF6 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs772510432; called by muse, mutect2
- NR0B1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs751208173, COSV66763733; called by muse, mutect2
- OR4K5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262020, COSV99081943; called by muse, mutect2
- OSBPL6 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99508759; called by muse, mutect2
- PCSK6 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs769776894; called by muse, mutect2, varscan2
- PHF2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs765726742, COSV100823100; called by muse, mutect2, varscan2
- RTL1 | c.4060G>C p.D1354H | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV66016884; called by muse, mutect2, varscan2
- RYR3 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 19/197 reads (10%) | catalogued as COSV101212605; called by muse, mutect2, varscan2
- SALL1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs750514153, COSV51760431, COSV51762914; called by muse, mutect2
- SLC15A4 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as rs967652202; called by muse, mutect2
- SLC35C2 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV54758354; called by muse, mutect2
- THSD7A | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 34/465 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV70264827; called by muse, mutect2
- TMEM229B | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as rs1241718024; called by muse, mutect2, varscan2
- TXNDC11 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 24/487 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.723); catalogued as rs1006072997; called by muse, mutect2
- UBR4 | c.3799G>T p.A1267S | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.956); catalogued as rs747214769; called by muse, mutect2
- AC090517.4 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ACTB | c.665A>T p.D222V | Missense Mutation (SNP) | VAF 24/794 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- AMOTL1 | c.1667A>G p.E556G | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ANKRD29 | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 54/776 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2
- APC | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 83/640 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ASAP1 | c.1731del p.A578Hfs*2 | Frame Shift Del (DEL) | VAF 47/249 reads (19%) | called by mutect2, pindel, varscan2
- CCDC57 | c.2082G>T p.E694D | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, varscan2
- CD200R1L | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 81/812 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD47 | c.480T>A p.F160L | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CPD | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- CPT1A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 54/662 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CSMD3 | c.3690G>A p.W1230* (on ENST00000297405 / NM_001363185.1; = p.W1126* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 48/868 reads (6%) | called by muse, mutect2
- FAM47A | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FAM83F | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.2796A>C p.Q932H | Missense Mutation (SNP) | VAF 20/831 reads (2%) | SIFT tolerated (0.06); PolyPhen benign (0.117); called by muse, mutect2
- GRIK1 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2
- GYPB | c.275G>C p.*92Sext*8 | Nonstop Mutation (SNP) | VAF 36/540 reads (7%) | called by muse, mutect2
- HEATR3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 47/503 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXA11 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.685); called by muse, mutect2
- HPS5 | c.2779G>T p.A927S (on ENST00000349215 / NM_181507.2; = p.A813S on NM_007216.4) | Missense Mutation (SNP) | VAF 21/672 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTR3C | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 29/406 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, mutect2
- INSM1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGA1 | c.1336T>G p.S446A | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF17 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); called by muse, mutect2
- LRRC47 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- NBPF12 | c.253del p.Q85Sfs*2 | Frame Shift Del (DEL) | VAF 99/887 reads (11%) | called by mutect2, pindel, varscan2
- NEFM | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 44/592 reads (7%) | called by muse, mutect2
- NKX3-2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NME8 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 54/740 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNT | c.3384G>C p.Q1128H | Missense Mutation (SNP) | VAF 67/443 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PHF12 | c.2422G>T p.V808L | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2
- PHKA1 | c.3034-2A>T p.X1012_splice | Splice Site (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- RFPL2 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 43/512 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.127); called by muse, mutect2
- RNF216 | c.1540G>A p.E514K (on ENST00000425013 / NM_207116.3; = p.E571K on NM_207111.4) | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- RPRD2 | c.680T>A p.L227H | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RUVBL2 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 118/430 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIN3A | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNRC18 | c.5368C>A p.P1790T | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- TRIM56 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- UACA | c.3499G>A p.A1167T | Missense Mutation (SNP) | VAF 42/385 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZDHHC17 | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ZNF451 | c.806C>A p.S269* | Nonsense Mutation (SNP) | VAF 8/227 reads (4%) | called by muse, mutect2
- ZNF536 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 72/534 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF783 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ADGRL3 | c.2881C>T p.L961= (on ENST00000506720 / NM_001322402.2; = p.L893= on NM_015236.6) | Silent (SNP) | VAF 56/513 reads (11%) | called by muse, mutect2, varscan2
- AHCTF1 | c.5776C>T p.L1926= (on ENST00000366508; = p.L1900= on NM_015446.5) | Silent (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- AMER2 | c.501G>C p.L167= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- BCL11B | c.1746C>T p.G582= (on ENST00000357195 / NM_001282237.2; = p.G511= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 159/473 reads (34%) | called by muse, mutect2, varscan2
- BST2 | c.387C>T p.D129= | Silent (SNP) | VAF 40/370 reads (11%) | catalogued as rs189347354, COSV53089974; called by muse, mutect2, varscan2
- EPPK1 | c.5655G>T p.T1885= | Silent (SNP) | VAF 36/298 reads (12%) | called by muse, varscan2
- FAM47A | c.1320C>T p.D440= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs775650386, COSV60494880, COSV60499976; called by muse, mutect2, varscan2
- FAM47A | c.1090C>T p.L364= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- H3C4 | c.168G>A p.Q56= | Silent (SNP) | VAF 17/409 reads (4%) | catalogued as rs1263235235, COSV61912132; called by muse, mutect2
- HDAC2 | c.1227A>C p.R409= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- LMOD2 | c.987G>A p.L329= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- NACAD | c.624G>C p.L208= | Silent (SNP) | VAF 26/295 reads (9%) | catalogued as COSV71989622; called by muse, mutect2
- NLRC4 | c.2196C>A p.I732= | Silent (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- NRXN3 | c.1899G>A p.A633= (on ENST00000335750 / NM_001330195.2; = p.A260= on NM_004796.6) | Silent (SNP) | VAF 50/512 reads (10%) | catalogued as rs1285579158, COSV100201405, COSV59771966; called by muse, mutect2
- PKP3 | c.369C>T p.S123= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs1440901075; called by muse, mutect2, varscan2
- PLEKHG4 | c.2052G>A p.Q684= | Silent (SNP) | VAF 39/580 reads (7%) | catalogued as COSV58571631; called by muse, mutect2
- RASAL1 | c.1714C>T p.L572= | Silent (SNP) | VAF 12/290 reads (4%) | catalogued as COSV55659686; called by muse, mutect2
- SCN8A | c.1167C>A p.I389= | Silent (SNP) | VAF 35/329 reads (11%) | catalogued as COSV100633455; called by muse, mutect2, varscan2
- SLC22A6 | c.153G>A p.P51= | Silent (SNP) | VAF 61/460 reads (13%) | catalogued as rs534770233; called by muse, mutect2, varscan2
- TTN | c.7950C>T p.G2650= (on ENST00000591111; = p.G2604= on NM_003319.4) | Silent (SNP) | VAF 48/398 reads (12%) | catalogued as rs773756480; called by muse, mutect2, varscan2
- TYW1 | c.2034C>T p.L678= | Silent (SNP) | VAF 46/398 reads (12%) | called by muse, mutect2
- VSIG1 | c.591C>T p.V197= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, varscan2
- XKR7 | c.783G>T p.L261= | Silent (SNP) | VAF 38/366 reads (10%) | called by muse, mutect2, varscan2
- ZNF114 | c.495C>T p.N165= | Silent (SNP) | VAF 22/229 reads (10%) | catalogued as rs772834220, COSV59944458; called by muse, mutect2
- ZNF7 | c.333C>T p.I111= | Silent (SNP) | VAF 23/310 reads (7%) | catalogued as rs767842674; called by muse, mutect2
- AL132655.6 | chr20:58840383 C>G | 5'Flank (SNP) | VAF 61/1393 reads (4%) | called by muse, mutect2
- ATG4B | c.538+234C>T | Intron (SNP) | VAF 11/102 reads (11%) | catalogued as rs1318926669; called by muse, varscan2
- CALM3 | c.3+667T>G | Intron (SNP) | VAF 43/243 reads (18%) | called by muse, mutect2, varscan2
- FBXL7 | c.740-1216C>T | Intron (SNP) | VAF 35/357 reads (10%) | catalogued as rs753206885, COSV100310463, COSV100310775; called by muse, mutect2
- FUBP1 | c.1927-42C>G | Intron (SNP) | VAF 28/239 reads (12%) | called by muse, mutect2, varscan2
- MOK | chr14:102224667 C>T | 3'Flank (SNP) | VAF 67/392 reads (17%) | called by muse, mutect2, varscan2
- NR4A2 | c.*45A>G | 3'UTR (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- NSG2 | c.213+1896C>T | Intron (SNP) | VAF 46/381 reads (12%) | called by muse, mutect2, varscan2
- PAH | c.*12G>A | 3'UTR (SNP) | VAF 16/380 reads (4%) | catalogued as COSV100188047; called by muse, mutect2
- PDGFC | c.119-11016A>G | Intron (SNP) | VAF 60/107 reads (56%) | called by muse, mutect2, varscan2
- POM121L4P | n.369G>A | RNA (SNP) | VAF 54/483 reads (11%) | catalogued as rs1458395551; called by muse, mutect2, varscan2
- PRKAG2 | c.-5G>A | 5'UTR (SNP) | VAF 22/593 reads (4%) | called by muse, mutect2
- SHCBP1L | c.-30G>A | 5'UTR (SNP) | VAF 32/219 reads (15%) | catalogued as rs924227761; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-62G>T | Intron (SNP) | VAF 78/1197 reads (7%) | called by muse, mutect2
- ZSCAN32 | c.915-188A>T | Intron (SNP) | VAF 45/632 reads (7%) | called by muse, mutect2
